Gene-level copy-number profile of tumor specimen TCGA-CV-5979-01A from TCGA case TCGA-CV-5979, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 26.2 years (9,567 days).
Specimen TCGA-CV-5979-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b6aa380a-bddf-484e-a06d-6a781610373c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-5979-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3fa47713-ff7c-4790-9dbc-b1fce06c3cc3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,127; copy number 2: 42,980; copy number 3: 5,480; copy number 4: 336; copy number 5: 347; copy number 6: 332; copy number 7: 34; copy number 8: 42; copy number 10: 35; copy number 11: 57; copy number 12: 10; copy number 13: 1; copy number 18: 12; copy number 22: 5; copy number 24: 1; copy number 35: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-5979-01A-11D-1682-01): tumor purity 0.86, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 896 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:28,548,135–29,600,868, 17 genes, copy number 6–7: AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1.
- chr5:29,948,828–29,983,114, 2 genes, copy number 6: RN7SKP207, AC018765.1.
- chr5:30,733,557–30,743,704, 1 gene, copy number 7: AC026433.1.
- chr5:31,639,131–32,110,932, 1 gene, copy number 6 (within-gene range 4–6): PDZD2.
- chr5:31,725,539–35,230,487, 71 genes, copy number 6–10 (broad region; genes not listed).
- chr5:39,888,576–44,066,731, 80 genes, copy number 5–11 (broad region; genes not listed).
- chr5:51,886,688–52,282,859, 5 genes, copy number 8: RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11.
- chr11:61,055,392–61,161,615, 4 genes, copy number 5: AP003721.2, CD5, VPS37C, AP000437.1.
- chr11:65,795,946–68,130,518, 151 genes, copy number 5 (broad region; genes not listed).
- chr11:69,438,365–70,436,584, 31 genes, copy number 7–10: AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,647,562, 4 genes, copy number 10: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.
- chr11:75,562,056–75,669,120, 6 genes, copy number 6–7: SERPINH1, AP001922.5, MAP6, AP001922.6, AP001922.2, AP001922.4.
- chr11:85,336,075–102,628,070, 304 genes, copy number 6–35 (broad region; genes not listed).
- chr14:99,158,416–101,077,910, 160 genes, copy number 5 (broad region; genes not listed).
- chr18:21,529,284–22,169,878, 23 genes, copy number 5 (within-gene range 1–5): ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1.
- chr18:22,175,465–22,176,662, 1 gene, copy number 5: AC091588.1.
- chr21:17,210,469–19,345,312, 35 genes, copy number 6–22: NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P.

Autosomal genes at a single copy (total copy number 1): 7,747. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
